Gene-level copy-number profile of tumor specimen HCM-SANG-1316-C18-06A-01D-A80T-32 from HCMI case HCM-SANG-1316-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1316-C18-06A-01D-A80T-32: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 129eca69-8147-44fd-ac12-1503c3ee0851.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1316-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,723 have no estimate.
https://portal.gdc.cancer.gov/files/34e21c1a-2117-4dfa-a17c-e0047a03a02d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 558; copy number 1: 17,634; copy number 2: 36,147; copy number 3: 2,276; copy number 4: 1,919; copy number 5: 365; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,508,806, 3 genes: AC119751.3, ANKRD20A17P, AC119751.5.
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:12,128,107–12,175,771, 4 genes (within-gene range 0–2): AC130366.1, USP17L7, USP17L2, FAM90A2P.
- chr8:12,393,209–12,665,588, 8 genes (within-gene range 0–1): DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1.
- chr9:41,974,362–42,011,610, 3 genes (within-gene range 0–1): RBM17P3, CR788268.1, RN7SL343P.
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr15:67,142,734–67,542,604, 7 genes (within-gene range 0–1): AC012568.1, AAGAB, RPS24P16, IQCH, IQCH-AS1, C15orf61, AC016355.1.
- chr15:67,627,852–67,629,135, 1 gene (within-gene range 0–1): HNRNPA1P5.
- chr16:6,873,899–6,874,005, 1 gene (within-gene range 0–1): RNU6-457P.
- chr18:12,192,203–12,201,979, 3 genes: PMM2P2, AP005264.5, AP005264.3.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–1): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 366 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:31,257,664–36,030,700, 186 genes, copy number 5 (broad region; genes not listed).
- chr20:43,189,998–45,101,127, 58 genes, copy number 5: AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT, GDAP1L1, FITM2, R3HDML, Y_RNA, AL117382.1, HNF4A, HNF4A-AS1, AL117382.2, MIR3646, LINC01620, RPL37AP1, TTPAL, SERINC3, PKIG, ADA, LINC01260, AL139352.1, KCNK15-AS1, CCN5, KCNK15, AL118522.1, RIMS4, PGBD4P2, YWHAB, PABPC1L, TOMM34, STK4-AS1, STK4, Y_RNA, KCNS1.
- chr20:49,219,295–51,562,831, 62 genes, copy number 5 (broad region; genes not listed).
- chr20:56,205,052–58,679,526, 60 genes, copy number 5–6 (within-gene range 4–6): RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB, APCDD1L, APCDD1L-DT, AL050327.1, LINC01711, STX16.

Autosomal genes at a single copy (total copy number 1): 15,292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
